Somatic mutation profile of tumor specimen C3L-02616-05 (aliquot CPT0192240006) from CPTAC case C3L-02616, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 63.7 years (23,275 days).
Specimen C3L-02616-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9f65974-55e6-4955-86a0-3bb5af522c3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02616-31 (Blood Derived Normal), aliquot CPT0192360002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3406ed5a-886a-4d87-91f4-5f64984dc8a7

The open-access MAF lists 201 somatic variants for this specimen: 138 protein-altering or splice-affecting, 40 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 121, Silent 40, Intron 11, 5'UTR 5, Splice Region 4, Splice Site 3, Nonsense Mutation 3, Frame Shift Ins 3, RNA 3, 3'UTR 2, Frame Shift Del 2, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 59/264 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SLC2A10 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 28/270 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771028960, CM080541; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 200/529 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS20 | c.4952G>A p.S1651N | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as rs763036919; called by muse, mutect2, varscan2
- ADGRE1 | c.2366C>T p.T789M | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs542411645, COSV51678425; called by muse, mutect2, varscan2
- ADGRG4 | c.2995C>A p.P999T | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs752342413; called by muse, mutect2, varscan2
- ASXL3 | c.4232C>A p.P1411Q | Missense Mutation (SNP) | VAF 54/245 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.671); catalogued as rs767761454, COSV52474984; called by muse, mutect2, varscan2
- BTBD17 | c.739G>A p.V247M | Missense Mutation (SNP) | VAF 132/380 reads (35%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.951); catalogued as rs1202764860; called by muse, mutect2, varscan2
- CBY2 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.176); catalogued as rs781536192, COSV60117510; called by muse, mutect2
- CCDC116 | c.1525C>T p.R509W | Missense Mutation (SNP) | VAF 54/327 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs756607786, COSV53041699, COSV99489180; called by muse, mutect2, varscan2
- COL5A2 | c.4070A>G p.N1357S | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as rs1163698455, COSV66411107; called by muse, mutect2, varscan2
- CORO7 | c.2479G>T p.V827L | Missense Mutation (SNP) | VAF 76/196 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.096); catalogued as COSV52034771; called by muse, mutect2, varscan2
- CSNK1E | c.738C>T p.S246= | Splice Region (SNP) | VAF 26/123 reads (21%) | catalogued as rs140218726; called by muse, mutect2, varscan2
- DNAH2 | c.3958C>T p.R1320W | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs200415226; called by mutect2, varscan2
- DUXA | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 56/194 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs768211378; called by muse, mutect2, varscan2
- EVC2 | c.2615G>T p.R872L | Missense Mutation (SNP) | VAF 121/392 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as COSV100186379; called by muse, mutect2, varscan2
- EYA4 | c.579C>T p.Y193= | Splice Region (SNP) | VAF 133/473 reads (28%) | catalogued as rs747954279, COSV62052786; called by muse, mutect2, varscan2
- FHL5 | c.160G>T p.D54Y | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100459801; called by muse, varscan2
- IDE | c.1631C>T p.A544V | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs375936259; called by muse, mutect2, varscan2
- ITGAL | c.1598G>T p.G533V | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63322009; called by muse, mutect2, varscan2
- ITPA | c.533G>T p.R178L | Missense Mutation (SNP) | VAF 91/489 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1230934159, COSV66264585; called by muse, mutect2, varscan2
- KLHL25 | c.1766C>T p.A589V | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.403); catalogued as rs143819696; called by muse, mutect2, varscan2
- LDLR | c.940G>A p.G314R | Missense Mutation (SNP) | VAF 120/303 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as rs72658858, CD1413607, CM071840, COSV52943474; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- LMBRD2 | c.1106A>G p.Y369C | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs777632901; called by muse, mutect2, varscan2
- LRFN2 | c.1508C>A p.T503K | Missense Mutation (SNP) | VAF 43/249 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57825240; called by muse, mutect2, varscan2
- MAB21L1 | c.870C>A p.D290E | Missense Mutation (SNP) | VAF 88/255 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV59772976; called by mutect2, varscan2
- MALRD1 | c.5776C>T p.H1926Y | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as rs983409801; called by muse, mutect2, varscan2
- MYH6 | c.3479C>A p.S1160Y | Missense Mutation (SNP) | VAF 143/703 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs750502101; called by muse, mutect2, varscan2
- OR2H2 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 86/318 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs773530562, COSV63542045; called by muse, mutect2, varscan2
- OR4A15 | c.83C>T p.T28I | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as rs1283156161, COSV59033926; called by muse, mutect2
- OR52H1 | c.325A>T p.N109Y (on ENST00000322653; = p.N115Y on NM_001005289.1) | Missense Mutation (SNP) | VAF 31/227 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs199611857; called by muse, mutect2, varscan2
- PAK6 | c.1303G>A p.V435I | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs765632390; called by muse, mutect2, varscan2
- PARP10 | c.854C>T p.T285M | Missense Mutation (SNP) | VAF 38/267 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.445); catalogued as rs782705803, COSV57299045; called by muse, mutect2, varscan2
- PBX1 | c.1222G>T p.A408S | Missense Mutation (SNP) | VAF 64/229 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV63341448; called by muse, mutect2, varscan2
- PDHA2 | c.152C>A p.T51N | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.066); catalogued as COSV54777730; called by muse, mutect2, varscan2
- PPP6R3 | c.2440del p.V814Sfs*56 (on ENST00000393800 / NM_001352375.2; = p.V734Sfs*56 on NM_018312.5) | Frame Shift Del (DEL) | VAF 20/139 reads (14%) | catalogued as COSV55722576; called by mutect2, pindel, varscan2
- PRAMEF12 | c.1199C>A p.T400N | Missense Mutation (SNP) | VAF 301/751 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as rs773192071; called by muse, mutect2, varscan2
- RTL1 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT tolerated (0.86); PolyPhen benign (0.138); catalogued as rs1054630090; called by muse, mutect2
- SLC2A7 | c.769C>A p.R257S | Missense Mutation (SNP) | VAF 43/314 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.262); catalogued as rs766692718; called by muse, mutect2, varscan2
- SUCLG2 | c.255G>T p.Q85H | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100213916; called by muse, mutect2, varscan2
- SYT14 | c.514A>T p.S172C | Missense Mutation (SNP) | VAF 106/332 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.525); catalogued as COSV55054451; called by muse, mutect2, varscan2
- TMX3 | c.1141C>T p.L381F | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868505578, COSV55184651; called by muse, mutect2, varscan2
- TRIML1 | c.580C>A p.Q194K | Missense Mutation (SNP) | VAF 60/185 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as rs753494682; called by muse, mutect2, varscan2
- TSC22D1 | c.2985G>C p.L995F (on ENST00000458659 / NM_183422.4; = p.L66F on NM_006022.4) | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV99817973; called by muse, mutect2
- TSPAN10 | c.8+1G>A p.X3_splice | Splice Site (SNP) | VAF 23/85 reads (27%) | catalogued as rs1237734490; called by muse, mutect2, varscan2
- UBN2 | c.2104C>T p.P702S | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.245); catalogued as COSV56027929; called by muse, mutect2, varscan2
- USP28 | c.2799G>T p.M933I | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV50197516; called by muse, mutect2, varscan2
- VWDE | c.110G>T p.S37I | Missense Mutation (SNP) | VAF 88/166 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs949626458; called by muse, mutect2, varscan2
- VWF | c.6893C>T p.T2298M | Missense Mutation (SNP) | VAF 62/397 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs774051063, COSV99780180; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF479 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 58/300 reads (19%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.916); catalogued as COSV58640258; called by muse, mutect2, varscan2
- ACACB | c.7255G>A p.V2419I | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- ACADM | c.682A>T p.T228S | Missense Mutation (SNP) | VAF 99/248 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADCY10 | c.4168+2del p.X1390_splice | Splice Site (DEL) | VAF 44/400 reads (11%) | called by mutect2, pindel*
- ADRB3 | c.627del p.S210Pfs*10 | Frame Shift Del (DEL) | VAF 132/526 reads (25%) | called by mutect2, pindel, varscan2
- ARID3C | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ATF7 | c.1069G>T p.A357S (on ENST00000548446 / NM_001366555.2; = p.A346S on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/501 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BNC1 | c.156C>A p.N52K | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2
- BRSK1 | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 46/151 reads (30%) | called by muse, mutect2, varscan2
- CACNA1E | c.1509G>T p.W503C | Missense Mutation (SNP) | VAF 69/218 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CALHM2 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 54/288 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- CCNDBP1 | c.331+6C>T | Splice Region (SNP) | VAF 39/107 reads (36%) | called by mutect2, varscan2
- CDC42EP5 | c.145C>G p.L49V | Missense Mutation (SNP) | VAF 58/210 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- CHD8 | c.1936A>G p.K646E (on ENST00000646647 / NM_001170629.2; = p.K367E on NM_020920.4) | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- CHEK1 | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2
- CMYA5 | c.5726G>T p.R1909I | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- COL6A1 | c.2215dup p.T739Nfs*23 | Frame Shift Ins (INS) | VAF 93/313 reads (30%) | called by mutect2, pindel, varscan2
- CRYBG2 | c.3893T>C p.I1298T | Missense Mutation (SNP) | VAF 35/282 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.065); called by muse, mutect2
- CTDP1 | c.2155G>A p.D719N | Missense Mutation (SNP) | VAF 72/609 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CYP11B1 | c.1102G>T p.A368S | Missense Mutation (SNP) | VAF 102/345 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- DCDC1 | c.1520C>T p.S507F | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- DNAH8 | c.10532C>G p.P3511R | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DRC7 | c.237_260del p.K79_T86del | In Frame Del (DEL) | VAF 28/140 reads (20%) | called by mutect2, pindel
- DTL | c.1425G>T p.K475N | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EMSY | c.679G>A p.V227I | Missense Mutation (SNP) | VAF 81/281 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- ESF1 | c.2451G>C p.K817N | Missense Mutation (SNP) | VAF 23/300 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.327); called by muse, mutect2
- FNDC3B | c.385C>G p.H129D | Missense Mutation (SNP) | VAF 27/235 reads (11%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- FRMPD2 | c.3142A>T p.S1048C | Missense Mutation (SNP) | VAF 30/344 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.416); called by muse, mutect2
- FSIP2 | c.4342C>A p.L1448M | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FUZ | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 129/492 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FXR2 | c.784G>T p.A262S | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- GNS | c.1096A>G p.K366E | Missense Mutation (SNP) | VAF 84/376 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GTPBP10 | c.71G>T p.R24M | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- HEMGN | c.597C>G p.D199E | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- HOXB5 | c.596C>A p.T199N | Missense Mutation (SNP) | VAF 80/273 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHV3-20 | c.85G>T p.G29C | Missense Mutation (SNP) | VAF 69/193 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- INHBB | c.525G>T p.Q175H | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- KCNJ1 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- KIAA1586 | c.290A>T p.H97L | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- KRTAP4-6 | c.424C>A p.P142T | Missense Mutation (SNP) | VAF 107/945 reads (11%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- L3MBTL1 | c.253A>G p.T85A (on ENST00000418998 / NM_001377303.1; = p.T63A on NM_032107.5) | Missense Mutation (SNP) | VAF 150/1067 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- LRRTM1 | c.473A>G p.H158R | Missense Mutation (SNP) | VAF 101/331 reads (31%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- MAP10 | c.2815A>C p.S939R | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- MAP10 | c.2816G>T p.S939I | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- MRC1 | c.2153C>T p.T718I | Missense Mutation (SNP) | VAF 39/369 reads (11%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- MROH5 | c.2098A>G p.K700E | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MUC2 | c.122dup p.N42Qfs*45 | Frame Shift Ins (INS) | VAF 26/88 reads (30%) | called by mutect2, pindel, varscan2
- MYO5A | c.2151A>T p.K717N | Missense Mutation (SNP) | VAF 62/522 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by mutect2, varscan2
- NBEAL1 | c.2209A>T p.T737S | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NEB | c.17246C>A p.T5749K | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NELL2 | c.2400G>A p.K800= | Splice Region (SNP) | VAF 38/316 reads (12%) | called by muse, mutect2, varscan2
- NLRP13 | c.1583G>T p.C528F | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- NPSR1 | c.594G>T p.W198C | Missense Mutation (SNP) | VAF 220/513 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NR5A2 | c.932G>T p.C311F (on ENST00000367362 / NM_205860.3; = p.C265F on NM_003822.5) | Missense Mutation (SNP) | VAF 135/461 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- NTSR1 | c.322C>A p.L108M | Missense Mutation (SNP) | VAF 70/497 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NWD2 | c.4429G>A p.D1477N | Missense Mutation (SNP) | VAF 78/222 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- OR10G3 | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 75/301 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- OR2G3 | c.532A>C p.I178L | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR2M7 | c.386C>A p.P129H | Missense Mutation (SNP) | VAF 46/244 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR3A3 | c.338T>A p.F113Y | Missense Mutation (SNP) | VAF 66/222 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- OR4N2 | c.151T>G p.S51A | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PACSIN3 | c.992C>G p.T331R | Missense Mutation (SNP) | VAF 58/418 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- PAX3 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.467); called by muse, mutect2
- PDZRN4 | c.147G>T p.R49S | Missense Mutation (SNP) | VAF 165/655 reads (25%) | SIFT tolerated, low confidence (0.15); called by muse, mutect2, varscan2
- PLEK2 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- POLR2B | c.2268G>C p.K756N | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- POU3F4 | c.142_156del p.S48_P52del | In Frame Del (DEL) | VAF 15/116 reads (13%) | called by mutect2, pindel
- PP2D1 | c.266C>A p.A89D | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- PSKH2 | c.1132G>T p.E378* | Nonsense Mutation (SNP) | VAF 15/119 reads (13%) | called by muse, mutect2, varscan2
- PTX3 | c.486C>A p.D162E | Missense Mutation (SNP) | VAF 74/596 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAD9B | c.1095G>T p.E365D | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- RPS6KC1 | c.3091-1G>T p.X1031_splice | Splice Site (SNP) | VAF 24/123 reads (20%) | called by muse, mutect2, varscan2
- SERINC4 | c.419T>A p.L140H | Missense Mutation (SNP) | VAF 40/260 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- SHISA9 | c.983G>T p.R328I | Missense Mutation (SNP) | VAF 71/295 reads (24%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- SHROOM3 | c.3914A>G p.K1305R | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC39A10 | c.1792dup p.C598Lfs*14 | Frame Shift Ins (INS) | VAF 14/75 reads (19%) | called by mutect2, pindel
- SLC4A3 | c.2240C>A p.T747N | Missense Mutation (SNP) | VAF 45/305 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNAP47 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEP1 | c.2912G>T p.G971V | Missense Mutation (SNP) | VAF 71/242 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); called by mutect2, varscan2
- TMEM132C | c.1821C>A p.D607E | Missense Mutation (SNP) | VAF 87/341 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TMEM63C | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 53/242 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TRIM58 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 42/230 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- UQCRC2 | c.683C>A p.P228H | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- VCAN | c.8036C>A p.T2679K | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- XRCC4 | c.733G>T p.G245W | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- ZFHX4 | c.3329C>T p.T1110I | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- ZNF695 | c.1105G>T p.E369* | Nonsense Mutation (SNP) | VAF 22/84 reads (26%) | called by muse, mutect2, varscan2
- ZNF776 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.142); called by muse, mutect2
- ZNF91 | c.2332G>T p.A778S | Missense Mutation (SNP) | VAF 69/239 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ABCA1 | c.1389C>T p.I463= | Silent (SNP) | VAF 26/185 reads (14%) | catalogued as rs376577965; called by muse, mutect2, varscan2
- ABCB4 | c.33C>A p.A11= | Silent (SNP) | VAF 223/562 reads (40%) | called by muse, mutect2, varscan2
- ANKRD27 | c.3000C>T p.S1000= | Silent (SNP) | VAF 112/540 reads (21%) | catalogued as rs747837816; called by muse, mutect2, varscan2
- ARHGEF5 | c.4695G>A p.Q1565= | Silent (SNP) | VAF 63/184 reads (34%) | called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1254G>A p.Q418= | Silent (SNP) | VAF 24/148 reads (16%) | called by muse, varscan2
- CACNA1H | c.3321C>T p.S1107= | Silent (SNP) | VAF 70/238 reads (29%) | called by muse, mutect2, varscan2
- CEP295NL | c.852G>T p.G284= | Silent (SNP) | VAF 47/205 reads (23%) | called by muse, mutect2, varscan2
- DIO3 | c.516G>A p.P172= | Silent (SNP) | VAF 156/566 reads (28%) | catalogued as rs1239039234, COSV100832165; called by muse, mutect2, varscan2
- DIS3 | c.2253T>C p.A751= | Silent (SNP) | VAF 42/376 reads (11%) | catalogued as COSV66705777; called by muse, mutect2, varscan2
- DLEC1 | c.1581A>T p.A527= | Silent (SNP) | VAF 33/115 reads (29%) | called by muse, mutect2, varscan2
- EPHA4 | c.313T>C p.L105= | Silent (SNP) | VAF 21/147 reads (14%) | called by muse, mutect2, varscan2
- ERC2 | c.771G>A p.E257= | Silent (SNP) | VAF 70/335 reads (21%) | called by muse, mutect2, varscan2
- EVX1 | c.750G>T p.P250= | Silent (SNP) | VAF 211/462 reads (46%) | called by muse, varscan2
- FAT3 | c.5079C>T p.I1693= | Silent (SNP) | VAF 24/143 reads (17%) | catalogued as rs771454774, COSV99965533; called by muse, mutect2, varscan2
- FSHR | c.1212G>T p.L404= | Silent (SNP) | VAF 157/408 reads (38%) | catalogued as rs771401071; called by muse, mutect2, varscan2
- GPALPP1 | c.75G>A p.R25= | Silent (SNP) | VAF 52/350 reads (15%) | called by muse, varscan2
- HOXD4 | c.336C>A p.A112= | Silent (SNP) | VAF 61/322 reads (19%) | called by muse, mutect2, varscan2
- KIAA1217 | c.216C>T p.P72= | Silent (SNP) | VAF 37/127 reads (29%) | catalogued as COSV64600168; called by muse, mutect2, varscan2
- LMBR1L | c.1344A>G p.T448= | Silent (SNP) | VAF 39/152 reads (26%) | catalogued as rs752952152; called by muse, mutect2, varscan2
- MAGI3 | c.3312C>A p.G1104= | Silent (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- MRC1 | c.2049G>T p.L683= | Silent (SNP) | VAF 27/236 reads (11%) | catalogued as rs1397609190; called by muse, mutect2, varscan2
- MYO10 | c.3996C>T p.T1332= | Silent (SNP) | VAF 69/362 reads (19%) | catalogued as rs1271130440; called by muse, mutect2, varscan2
- NLRP10 | c.987G>A p.T329= | Silent (SNP) | VAF 42/243 reads (17%) | catalogued as COSV60780787; called by muse, mutect2, varscan2
- NLRP2 | c.927G>A p.E309= | Silent (SNP) | VAF 79/280 reads (28%) | catalogued as COSV54755551; called by muse, mutect2, varscan2
- NUFIP1 | c.60G>C p.L20= | Silent (SNP) | VAF 96/655 reads (15%) | called by muse, mutect2, varscan2
- OR4K5 | c.792C>A p.I264= | Silent (SNP) | VAF 53/312 reads (17%) | catalogued as COSV60002497; called by muse, mutect2, varscan2
- PARG | c.774G>T p.V258= | Silent (SNP) | VAF 64/399 reads (16%) | called by muse, mutect2, varscan2
- PCGF2 | c.249C>G p.V83= | Silent (SNP) | VAF 65/479 reads (14%) | called by muse, mutect2, varscan2
- PDCD6IP | c.2238C>G p.T746= | Silent (SNP) | VAF 50/200 reads (25%) | called by muse, mutect2, varscan2
- PROSER3 | c.1308G>A p.A436= | Silent (SNP) | VAF 10/136 reads (7%) | called by muse, mutect2
- PTCHD4 | c.309G>T p.S103= | Silent (SNP) | VAF 20/208 reads (10%) | called by muse, mutect2
- SLCO3A1 | c.942C>T p.P314= | Silent (SNP) | VAF 73/271 reads (27%) | catalogued as rs1280361473; called by muse, mutect2, varscan2
- SNX14 | c.411C>T p.L137= | Silent (SNP) | VAF 46/138 reads (33%) | called by muse, mutect2, varscan2
- STYXL2 | c.2112C>A p.T704= | Silent (SNP) | VAF 20/110 reads (18%) | called by muse, mutect2, varscan2
- SYTL2 | c.30G>A p.E10= | Silent (SNP) | VAF 52/168 reads (31%) | catalogued as rs771534463; called by muse, mutect2, varscan2
- TMEM132B | c.903C>T p.V301= | Silent (SNP) | VAF 35/128 reads (27%) | catalogued as COSV54757808; called by muse, mutect2, varscan2
- UNC93A | c.1194C>A p.A398= | Silent (SNP) | VAF 44/306 reads (14%) | called by muse, varscan2
- ZNF234 | c.1410A>T p.R470= | Silent (SNP) | VAF 54/167 reads (32%) | called by muse, mutect2, varscan2
- ZNF385A | c.1155G>C p.P385= (on ENST00000338010 / NM_001130967.3; = p.P365= on NM_015481.3) | Silent (SNP) | VAF 6/20 reads (30%) | called by muse, varscan2
- ZNF469 | c.7869C>G p.V2623= (on ENST00000437464; = p.V2651= on NM_001367624.2) | Silent (SNP) | VAF 294/765 reads (38%) | catalogued as rs1319188011; called by muse, mutect2, varscan2
- ADAMTS17 | c.616+24318A>G | Intron (SNP) | VAF 31/168 reads (18%) | catalogued as rs778775049; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73845497 G>A | 5'Flank (SNP) | VAF 53/101 reads (52%) | catalogued as rs755677532; called by muse, mutect2, varscan2
- C2orf83 | n.447G>A | RNA (SNP) | VAF 65/368 reads (18%) | called by muse, mutect2, varscan2
- CHRNB2 | c.-42G>T | 5'UTR (SNP) | VAF 49/290 reads (17%) | catalogued as rs776350897, COSV63807869; called by muse, mutect2, varscan2
- CSF2RA | c.77-45G>T | Intron (SNP) | VAF 37/130 reads (28%) | catalogued as COSV62625649; called by muse, varscan2
- FABP5P3 | chr7:152445673 A>T | 3'Flank (SNP) | VAF 76/202 reads (38%) | called by muse, mutect2, varscan2
- H3C1 | c.-5C>T | 5'UTR (SNP) | VAF 27/183 reads (15%) | catalogued as rs758620711; called by muse, mutect2, varscan2
- IGHV3-66 | c.-4C>A | 5'UTR (SNP) | VAF 94/424 reads (22%) | catalogued as rs782200125; called by muse, varscan2
- KCNH7 | c.2154+53C>A | Intron (SNP) | VAF 10/71 reads (14%) | catalogued as COSV100034899, COSV59812217, COSV59812225; called by muse, mutect2, varscan2
- NOTCH2 | c.2479+42G>A | Intron (SNP) | VAF 71/238 reads (30%) | called by muse, mutect2, varscan2
- NRP2 | c.2440+9594G>T | Intron (SNP) | VAF 88/503 reads (17%) | called by muse, mutect2, varscan2
- NXNL1 | c.-31G>T | 5'UTR (SNP) | VAF 25/169 reads (15%) | called by muse, mutect2, varscan2
- PDE4DIP | c.637-7353G>C | Intron (SNP) | VAF 51/273 reads (19%) | called by muse, mutect2, varscan2
- POGZ | c.2234+17A>T | Intron (SNP) | VAF 4/41 reads (10%) | called by mutect2, varscan2
- PTPRC | c.100+1700T>A | Intron (SNP) | VAF 37/163 reads (23%) | called by muse, mutect2, varscan2
- PTS | c.163+40G>T | Intron (SNP) | VAF 44/142 reads (31%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.3660A>G | RNA (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- SELENOW | c.30-638C>G | Intron (SNP) | VAF 25/80 reads (31%) | called by muse, mutect2, varscan2
- ST18 | c.-10C>T | 5'UTR (SNP) | VAF 20/160 reads (13%) | called by muse, mutect2, varscan2
- USH2A | c.7451+21A>T | Intron (SNP) | VAF 48/299 reads (16%) | called by muse, mutect2, varscan2
- WNT3A | c.*793C>A | 3'UTR (SNP) | VAF 35/85 reads (41%) | called by muse, mutect2, varscan2
- WWOX | c.*11G>C | 3'UTR (SNP) | VAF 21/134 reads (16%) | catalogued as COSV101283068; called by muse, mutect2, varscan2
- ZNF971P | n.957G>A | RNA (SNP) | VAF 87/327 reads (27%) | called by muse, mutect2, varscan2
